Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A39X, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A39X-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Gallbladder (9 x 3 x 0.8 cm) and liver segments V and VI (220 grams; 10 x 8 x 5.5 cm). A1, B1, B2, B3, B4, B5

DIAGNOSIS:

Liver segments V and VI, resection: Grade 2 (of 4) hepatocellular carcinoma forming a 6.5 x 6 x 5.5 cm mass located in segment V and VI of the liver. The tumor does not invade through the hepatic capsule. The margins are widely free of tumor by 2 cm. The non-neoplastic liver is grossly non-cirrhotic.

Gallbladder, cholecystectomy: Cholesterolosis. No stones are identified. Negative for malignancy.

ICD-O-3
carcinoma, hepatocellular, NOS 8170/3
Site liver c22.0
lw 9/22/11

Source: NCI Genomic Data Commons file 73298117-90a3-451e-ba74-812e5e4ff773 (TCGA-DD-A39X.B9919D23-7D65-4295-84D5-6678B26BEA01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).